Somatic mutation profile of tumor specimen MP2PRT-PASUZE-TMP1-A (aliquot MP2PRT-PASUZE-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASUZE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.7 years (2,822 days).
Specimen MP2PRT-PASUZE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1afd9e0-b70a-41ba-baf6-2880dab9dc46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASUZE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASUZE-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81070c97-618d-48fb-86ba-2a9bd32cc633

The open-access MAF lists 85 somatic variants for this specimen: 64 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 18, Nonsense Mutation 3, Splice Region 2, Frame Shift Del 1, 5'UTR 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMBRA1 | c.2937C>G p.F979L (on ENST00000458649 / NM_001367468.1; = p.F889L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/470 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); catalogued as COSV54062612; called by muse, mutect2
- ASB15 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs1425484873; called by muse, mutect2
- CACTIN | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 55/684 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as rs775217403, COSV99698401; called by muse, mutect2
- CD27 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1454594029; called by muse, mutect2, varscan2
- CFH | c.2195C>T p.T732M | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs201360629, CM124965, COSV66410451; called by muse, mutect2, varscan2
- CRTAC1 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 67/652 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs758769483; called by muse, mutect2, varscan2
- CYB561D1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 46/598 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs745785611; called by muse, mutect2
- CYP2F1 | c.825G>A p.E275= | Splice Region (SNP) | VAF 51/267 reads (19%) | catalogued as rs972713547; called by muse, mutect2, varscan2
- EML2 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.391); catalogued as COSV99840396; called by muse, mutect2
- FAM153B | c.730G>T p.V244L (on ENST00000253490; = p.V167L on NM_001265615.1) | Missense Mutation (SNP) | VAF 74/604 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.22); catalogued as COSV99499200; called by muse, mutect2, varscan2
- GLI3 | c.2204G>A p.G735E | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.141); catalogued as COSV67887920; called by muse, mutect2
- GRIN3A | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs754089982, COSV62453382; called by muse, mutect2
- IPO7 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 92/269 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65685260; called by muse, mutect2, varscan2
- LGALS12 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1320189429, COSV55370202; called by muse, mutect2, varscan2
- MALRD1 | c.4271G>A p.R1424Q | Missense Mutation (SNP) | VAF 38/602 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747079785; called by muse, mutect2
- MYO18B | c.7153C>T p.R2385W | Missense Mutation (SNP) | VAF 69/480 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs767625703, COSV59128196; called by muse, mutect2, varscan2
- NSD2 | c.1172G>C p.R391T | Missense Mutation (SNP) | VAF 42/471 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100372726; called by muse, mutect2
- OXGR1 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 100/412 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1286500757, COSV100036943; called by muse, mutect2, varscan2
- PKHD1L1 | c.6619C>G p.L2207V | Missense Mutation (SNP) | VAF 33/379 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as COSV65737656; called by muse, mutect2
- POM121L12 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 219/644 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV68692577; called by muse, mutect2, varscan2
- RNF17 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 36/352 reads (10%) | catalogued as COSV55036205; called by muse, mutect2, varscan2
- SLC9A3R2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 58/583 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.536); catalogued as rs370860382; called by muse, mutect2, varscan2
- SNCG | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 327/615 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs199851904; called by muse, mutect2, varscan2
- STAB2 | c.6650G>A p.R2217K | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV66344726; called by muse, mutect2, varscan2
- YTHDF3 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 33/419 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV101572355; called by muse, mutect2
- YTHDF3 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 46/386 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV72773752; called by muse, mutect2, varscan2
- ZBTB22 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 38/752 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs781066606; called by muse, mutect2
- ADAMTS9 | c.1278G>C p.L426F | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGRN | c.4769G>A p.S1590N | Missense Mutation (SNP) | VAF 65/689 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ANXA9 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 137/389 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ARHGAP18 | c.1979C>G p.S660* | Nonsense Mutation (SNP) | VAF 24/187 reads (13%) | called by muse, mutect2, varscan2
- BATF2 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 95/408 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- BICC1 | c.483A>C p.E161D | Missense Mutation (SNP) | VAF 46/552 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- CCDC88A | c.3418G>C p.E1140Q | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CDS1 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEMIP2 | c.937del p.A313Lfs*17 | Frame Shift Del (DEL) | VAF 147/394 reads (37%) | called by mutect2, pindel, varscan2
- CFAP47 | c.2153G>T p.R718I | Missense Mutation (SNP) | VAF 97/112 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CREBBP | c.4974T>G p.C1658W | Missense Mutation (SNP) | VAF 214/536 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- DCDC1 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- DCUN1D4 | c.811G>A p.E271K (on ENST00000334635 / NM_001287757.1; = p.E236K on NM_015115.3) | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DDX21 | c.1624C>G p.Q542E | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2
- FAM153A | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- FBN2 | c.3300C>A p.C1100* | Nonsense Mutation (SNP) | VAF 12/427 reads (3%) | called by muse, mutect2
- FZD10 | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 204/578 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- GABRB1 | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAREM1 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GOLGB1 | c.3991G>A p.E1331K | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- IFIH1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 77/351 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- KCNH7 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 19/310 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2
- KREMEN2 | c.982G>C p.D328H | Missense Mutation (SNP) | VAF 184/437 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- LRRC9 | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 83/310 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- MED12L | c.3946C>G p.Q1316E | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- METTL2A | c.898C>G p.Q300E | Missense Mutation (SNP) | VAF 28/399 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2
- OR2V1 | c.590A>G p.D197G | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2
- OXA1L | c.497C>T p.A166V (on ENST00000285848; = p.A106V on NM_005015.5) | Missense Mutation (SNP) | VAF 79/358 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- OXTR | c.423C>G p.I141M | Missense Mutation (SNP) | VAF 96/679 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PLAGL1 | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- POLK | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- TBC1D30 | c.2713C>T p.P905S (on ENST00000542120; = p.P742S on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/388 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TCP11 | c.1498G>T p.V500L (on ENST00000512012; = p.V438L on NM_018679.5) | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2
- VSIG4 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 103/266 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- YTHDF3 | c.1737G>A p.E579= | Splice Region (SNP) | VAF 27/161 reads (17%) | called by muse, mutect2, varscan2
- ZNF33A | c.1577G>C p.C526S (on ENST00000458705 / NM_006974.3; = p.C527S on NM_006954.2) | Missense Mutation (SNP) | VAF 22/664 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF700 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ACSL6 | c.999C>T p.V333= (on ENST00000379240; = p.V358= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/195 reads (44%) | catalogued as rs749597885, COSV57302956; called by muse, mutect2, varscan2
- AOC1 | c.1161C>T p.P387= | Silent (SNP) | VAF 59/519 reads (11%) | catalogued as rs751075124, COSV62868875; called by muse, mutect2, varscan2
- BRINP3 | c.1110G>A p.Q370= | Silent (SNP) | VAF 39/446 reads (9%) | catalogued as COSV66512789; called by muse, mutect2
- COA6 | c.258C>T p.F86= | Silent (SNP) | VAF 81/210 reads (39%) | catalogued as rs760951357; called by muse, mutect2, varscan2
- GLUD2 | c.1176C>T p.N392= | Silent (SNP) | VAF 98/258 reads (38%) | catalogued as rs1242855174, COSV60151317; called by muse, mutect2, varscan2
- GOLGB1 | c.7251G>A p.L2417= | Silent (SNP) | VAF 148/414 reads (36%) | catalogued as COSV61465618; called by muse, mutect2, varscan2
- KRIT1 | c.135G>A p.Q45= | Silent (SNP) | VAF 20/186 reads (11%) | catalogued as rs1475255131; called by muse, varscan2
- MYH8 | c.2088G>A p.L696= | Silent (SNP) | VAF 28/343 reads (8%) | called by muse, mutect2
- PCDH17 | c.54C>T p.L18= | Silent (SNP) | VAF 59/432 reads (14%) | called by muse, mutect2, varscan2
- PDE11A | c.6G>A p.L2= | Silent (SNP) | VAF 72/237 reads (30%) | called by muse, mutect2, varscan2
- POU6F2 | c.639G>A p.S213= | Silent (SNP) | VAF 102/823 reads (12%) | catalogued as rs770871137; called by muse, mutect2, varscan2
- RARA | c.1386G>A p.P462= | Silent (SNP) | VAF 73/403 reads (18%) | catalogued as rs776342037, COSV99564362; called by muse, mutect2, varscan2
- ROBO3 | c.3564C>T p.L1188= | Silent (SNP) | VAF 61/420 reads (15%) | called by muse, mutect2, varscan2
- RTCB | c.612C>T p.P204= | Silent (SNP) | VAF 48/460 reads (10%) | catalogued as rs267606232, COSV53277180; called by muse, mutect2
- RYR1 | c.4377C>T p.H1459= | Silent (SNP) | VAF 40/428 reads (9%) | catalogued as rs772882086, COSV62097548; called by muse, mutect2
- SCARA3 | c.1002C>T p.Y334= | Silent (SNP) | VAF 53/343 reads (15%) | catalogued as rs140763076, COSV57269547; called by muse, mutect2, varscan2
- SLC6A1 | c.978C>T p.I326= | Silent (SNP) | VAF 51/287 reads (18%) | called by muse, mutect2, varscan2
- SRBD1 | c.2073C>G p.L691= | Silent (SNP) | VAF 26/290 reads (9%) | catalogued as rs748388517; called by muse, mutect2
- DBNDD1 | chr16:90019809 C>T | 5'Flank (SNP) | VAF 50/651 reads (8%) | catalogued as rs546595932, COSV50022889; called by muse, mutect2
- FAM180B | c.-4G>A | 5'UTR (SNP) | VAF 158/477 reads (33%) | catalogued as rs749221249; called by muse, mutect2, varscan2
- IGHV2-70 | chr14:106770576 ins CCC | 3'Flank (INS) | VAF 49/63 reads (78%) | called by mutect2, pindel, varscan2
